CCDI case PBCNMY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/d06e8ef8-520e-47ad-9baa-1e613696edc8

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.8 years (650 days).

Biospecimens (2 samples)
- Sample 0DW2VN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DW2W8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
